Somatic mutation profile of tumor specimen TCGA-AG-3893-01A (aliquot TCGA-AG-3893-01A-01W-1073-09) from TCGA case TCGA-AG-3893, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.7 years (27,272 days).
Specimen TCGA-AG-3893-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9db0cf98-2a5f-4ad8-b402-1fc28c9595c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3893-10A (Blood Derived Normal), aliquot TCGA-AG-3893-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbf77db7-c789-40fa-b91a-c3da3b259154

The open-access MAF lists 144 somatic variants for this specimen: 100 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 38, Intron 3, Frame Shift Del 3, Nonsense Mutation 3, RNA 3, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4067C>G p.S1356* | Nonsense Mutation (SNP) | VAF 199/259 reads (77%) | catalogued as rs1554085480, COSV57325773, COSV57330189, COSV57333960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX4 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917718, CM073257, COSV58387987; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4291G>T p.A1431S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52199328; called by muse, mutect2, varscan2
- ACKR4 | c.602A>T p.Q201L | Missense Mutation (SNP) | VAF 134/391 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.314); catalogued as COSV51442375; called by muse, mutect2, varscan2
- AHNAK2 | c.5422G>T p.D1808Y | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV60913100; called by muse, mutect2, varscan2
- ALDH1L2 | c.2750A>T p.K917M | Missense Mutation (SNP) | VAF 9/266 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311141; called by muse, mutect2
- AMBN | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV59825868; called by muse, mutect2, varscan2
- ARHGAP21 | c.1648C>G p.H550D | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV57604453, COSV57604766; called by muse, mutect2
- ATP11C | c.1309G>T p.V437L | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV59562363; called by muse, mutect2, varscan2
- BMPER | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1483511272, COSV51819417; called by muse, mutect2, varscan2
- BPIFB6 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs202105575, COSV62754954; called by muse, mutect2, varscan2
- BTN1A1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778400918, COSV55067292; called by muse, mutect2
- CACHD1 | c.2228A>G p.Y743C | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51551885; called by muse, mutect2, varscan2
- CACNA2D1 | c.2521T>G p.C841G (on ENST00000356253 / NM_001366867.1; = p.C829G on NM_000722.4) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV62377440; called by muse, mutect2, varscan2
- CADPS | c.3775G>T p.D1259Y | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV51875524; called by muse, mutect2, varscan2
- CALCOCO1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs900627188, COSV50413407; called by muse, mutect2, varscan2
- CARMIL1 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs866053703, COSV61516365; called by muse, mutect2, varscan2
- CEP68 | c.1973T>A p.L658H | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99561044; called by muse, mutect2
- CRMP1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs147608754; called by muse, mutect2
- CSMD1 | c.2104G>T p.G702C (on ENST00000520002; = p.G701C on NM_033225.6) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100150103; called by muse, mutect2
- CUL2 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101039202; called by muse, mutect2
- DLG2 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.334); catalogued as COSV65836119; called by muse, mutect2
- DOCK8 | c.5381A>T p.Y1794F | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV66619356; called by muse, mutect2, varscan2
- EFCAB1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50618163; called by muse, mutect2
- ERAP1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99701061; called by muse, mutect2
- F7 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs764807079, CM001149, COSV60644962; called by muse, varscan2
- FAT3 | c.7504G>A p.V2502I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs757504785, COSV53071433, COSV53099482; called by muse, mutect2, varscan2
- FERMT3 | c.1568G>A p.R523Q (on ENST00000279227 / NM_178443.3; = p.R519Q on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1383121861, COSV54178776; called by muse, mutect2, varscan2
- FPR2 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 139/407 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60672545; called by muse, mutect2, varscan2
- GAS7 | c.1019G>A p.R340Q (on ENST00000432992 / NM_201433.2; = p.R200Q on NM_003644.3) | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1325240094, COSV60432781, COSV60437600; called by muse, mutect2, varscan2
- GLE1 | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59407402; called by muse, mutect2, varscan2
- GPR158 | c.2534A>T p.E845V | Missense Mutation (SNP) | VAF 161/472 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100893868; called by muse, mutect2, varscan2
- GPR158 | c.2535A>T p.E845D | Missense Mutation (SNP) | VAF 161/472 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV100893869; called by muse, mutect2, varscan2
- HDAC9 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV67771354; called by muse, mutect2, varscan2
- HMGCLL1 | c.484-1G>C p.X162_splice | Splice Site (SNP) | VAF 20/82 reads (24%) | catalogued as COSV51443337; called by muse, mutect2, varscan2
- HRNR | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.601); catalogued as COSV64256836; called by muse, mutect2, varscan2
- IQCG | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as COSV54561608; called by muse, mutect2, varscan2
- ITGAM | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs761171328, COSV54936244; called by muse, mutect2, varscan2
- KDR | c.2129A>G p.D710G | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as COSV99818068; called by muse, mutect2
- LAG3 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as rs1371693344, COSV52567150; called by muse, mutect2, varscan2
- LAMC3 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs777086759, COSV63090346; called by muse, mutect2, varscan2
- LAMP5 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs755490520, COSV55715855; called by muse, mutect2, varscan2
- LILRB5 | c.1756G>T p.A586S (on ENST00000449561 / NM_001081442.3; = p.A585S on NM_006840.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs201610708, COSV60256617; called by muse, mutect2, varscan2
- LRGUK | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150378173; called by muse, mutect2, varscan2
- LSM2 | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV65150366; called by muse, mutect2, varscan2
- LSS | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs199896537; called by muse, mutect2, varscan2
- MACROH2A1 | c.1098G>C p.M366I (on ENST00000510038; = p.M365I on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV56894410; called by muse, mutect2, varscan2
- MBD6 | c.2247_2248del p.S750Tfs*42 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as COSV63074007; called by mutect2, pindel, varscan2
- MPDZ | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59939164; called by muse, mutect2, varscan2
- MPEG1 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 171/473 reads (36%) | catalogued as rs759351832, COSV57089807; called by muse, mutect2, varscan2
- NCOA6 | c.4579A>G p.K1527E | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1402717581, COSV100750240, COSV62862878; called by muse, mutect2, varscan2
- NEK1 | c.1804C>A p.R602S | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV71454621, COSV71455572; called by muse, mutect2, varscan2
- NELL2 | c.2386C>T p.L796F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs986658381, COSV100419941, COSV100420856; called by muse, mutect2
- NTRK3 | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100713115; called by muse, mutect2
- OR5D16 | c.838T>C p.Y280H | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV101004038; called by muse, mutect2
- OR8H3 | c.466T>A p.S156T | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV57908496; called by muse, mutect2
- OTUD7B | c.694A>G p.R232G | Missense Mutation (SNP) | VAF 126/320 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64915890; called by muse, mutect2, varscan2
- PARD6G | c.95T>C p.F32S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62060904; called by muse, mutect2, varscan2
- PCDHA13 | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.106); catalogued as rs1554178526, COSV56493827; called by muse, mutect2, varscan2
- PHEX | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs149168023, CM104912, COSV65074937; called by muse, mutect2
- PKHD1 | c.10660G>C p.E3554Q | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64386909, COSV64391751; called by muse, mutect2, varscan2
- PLCL2 | c.2422G>A p.A808T (on ENST00000615277 / NM_001144382.2; = p.A682T on NM_015184.5) | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs148180373; called by muse, mutect2
- PTCH2 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as rs200534670, COSV64710761; called by muse, mutect2, varscan2
- PTPRM | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59854523; called by muse, mutect2, varscan2
- RIPOR2 | c.527T>G p.L176R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52419916; called by muse, mutect2, varscan2
- RNF213 | c.13658C>T p.T4553M | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60391162, COSV60395161; called by muse, mutect2, varscan2
- RP1 | c.3452A>T p.H1151L | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55114802, COSV99608598; called by muse, mutect2, varscan2
- RTL4 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 654/761 reads (86%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV61206218; called by muse, mutect2, varscan2
- RYR2 | c.1291A>T p.R431W | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63702394; called by muse, mutect2
- SACS | c.13581A>C p.E4527D | Missense Mutation (SNP) | VAF 85/387 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV66538506; called by muse, mutect2, varscan2
- SCN10A | c.4709C>T p.T1570M | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772484960, COSV101479190, COSV71860989; ClinVar: uncertain significance; called by muse, mutect2
- SETD5 | c.3716A>G p.Y1239C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56709722; called by muse, mutect2, varscan2
- SLC12A9 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as rs768757934, COSV51932593; called by muse, mutect2, varscan2
- SMR3A | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 246/801 reads (31%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.058); catalogued as COSV56949742, COSV56949930; called by muse, mutect2, varscan2
- SNX29 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372445217; called by muse, mutect2, varscan2
- SPAM1 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 93/379 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.055); catalogued as COSV56142846; called by muse, mutect2, varscan2
- TBX5 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV59860225; called by muse, mutect2, varscan2
- TECTA | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV50700919; called by muse, mutect2, varscan2
- TET3 | c.1585C>A p.Q529K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV59880679; called by muse, mutect2, varscan2
- THOC2 | c.2415T>G p.N805K | Missense Mutation (SNP) | VAF 60/833 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.122); catalogued as COSV55544359; called by muse, mutect2
- THSD7A | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935456770, COSV70263729; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPTE2 | c.538C>T p.R180* (on ENST00000400230 / NM_199254.2; = p.R103* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 59/195 reads (30%) | catalogued as rs202071055, COSV55027795; called by muse, mutect2, varscan2
- TRIM55 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99396934; called by muse, mutect2
- TXLNB | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs915719731, COSV64443749; called by muse, mutect2, varscan2
- UGT1A4 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV100531411, COSV59386934; called by muse, mutect2, varscan2
- UMOD | c.1578-2A>G p.X526_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100208484; called by muse, mutect2, varscan2
- WASF1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV55619363; called by muse, mutect2, varscan2
- ZDHHC21 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66613179; called by muse, mutect2, varscan2
- ZFPM2 | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779236742, COSV65872983; called by muse, mutect2, varscan2
- ZIM3 | c.1147A>C p.K383Q | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV54139839, COSV54145831; called by muse, mutect2, varscan2
- ZNF407 | c.4138A>T p.I1380L | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV55249538; called by muse, mutect2, varscan2
- ZNF610 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV100017068, COSV58344418; called by muse, mutect2
- ZNF804B | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV100302343, COSV100304552; called by muse, mutect2
- ZNF99 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101233777, COSV68055476; called by muse, mutect2, varscan2
- F8 | c.3174dup p.K1059* | Frame Shift Ins (INS) | VAF 98/456 reads (21%) | called by pindel, varscan2*
- GGNBP2 | c.1423A>C p.S475R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MPP5 | c.227dup p.Q77Afs*4 | Frame Shift Ins (INS) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- POC5 | c.868_872del p.V291Afs*17 (on ENST00000428202 / NM_001099271.2; = p.V266Afs*17 on NM_152408.2) | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- RFPL3 | c.927_933delinsGTG p.P310Cfs*24 (on ENST00000249007 / NM_001098535.1; = p.P281Cfs*24 on NM_006604.2) | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by pindel, varscan2*
- ACACA | c.4938G>A p.L1646= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- ACKR3 | c.18C>T p.F6= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs750658947, COSV56021253; called by muse, mutect2, varscan2
- AKNA | c.882A>G p.E294= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV56312196; called by muse, mutect2, varscan2
- ALDH1L2 | c.2748C>T p.T916= | Silent (SNP) | VAF 9/266 reads (3%) | catalogued as COSV99311142; called by muse, mutect2
- ANKAR | c.2836C>T p.L946= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs540415324, COSV55611615; called by muse, mutect2, varscan2
- AQP9 | c.480C>T p.N160= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs562183896, COSV54967546; called by muse, mutect2, varscan2
- C4orf17 | c.318G>A p.V106= | Silent (SNP) | VAF 142/283 reads (50%) | catalogued as rs376797865; called by muse, mutect2, varscan2
- CEP250 | c.7173C>T p.L2391= | Silent (SNP) | VAF 48/229 reads (21%) | catalogued as COSV61169466; called by muse, mutect2, varscan2
- CLVS1 | c.753T>C p.H251= | Silent (SNP) | VAF 67/213 reads (31%) | catalogued as COSV57973599; called by muse, mutect2, varscan2
- CPN1 | c.1371T>G p.P457= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV100962650; called by muse, mutect2
- DNAH9 | c.6153G>C p.L2051= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV52345225; called by muse, mutect2, varscan2
- DSP | c.6039G>A p.R2013= | Silent (SNP) | VAF 5/125 reads (4%) | catalogued as COSV65791597, COSV65793566; called by muse, mutect2
- ESRP2 | c.897C>G p.G299= (on ENST00000565858 / NM_001365264.1; = p.G289= on NM_024939.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs570243647, COSV52173022; called by muse, mutect2, varscan2
- FBXO7 | c.408C>T p.D136= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs776288097, COSV56677139; called by muse, mutect2, varscan2
- HELZ | c.1272G>A p.L424= | Silent (SNP) | VAF 13/155 reads (8%) | catalogued as COSV62377701; called by muse, mutect2
- HNRNPL | c.1176T>G p.S392= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV55492118; called by muse, mutect2, varscan2
- KCNA1 | c.543C>T p.I181= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV66837070; called by muse, mutect2, varscan2
- KIDINS220 | c.4404C>T p.N1468= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs77234849, COSV56750716; called by muse, mutect2, varscan2
- LIFR | c.1992G>A p.S664= | Silent (SNP) | VAF 107/302 reads (35%) | catalogued as rs142392717; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRPPRC | c.3339G>A p.T1113= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV53237265; called by muse, mutect2, varscan2
- MAGEE2 | c.120C>G p.V40= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV64897570; called by muse, mutect2, varscan2
- MAP7 | c.345G>A p.Q115= | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as rs1212862313, COSV100643939; called by muse, mutect2
- NLRP7 | c.1479C>T p.H493= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs763029701, COSV60171565; called by muse, mutect2, varscan2
- NYNRIN | c.5310G>A p.E1770= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs534007372, COSV66842036; called by muse, mutect2, varscan2
- PCDH10 | c.1317C>T p.G439= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52089540; called by muse, mutect2, varscan2
- PCDHA12 | c.1362G>A p.A454= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV56481412; called by muse, mutect2, varscan2
- PCDHB2 | c.1113C>T p.S371= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV50569352; called by muse, mutect2, varscan2
- PHLPP1 | c.4578C>G p.S1526= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53026733; called by muse, mutect2, varscan2
- PMS2 | c.2148C>T p.T716= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as rs748404138, COSV56221036; ClinVar: likely benign; called by muse, mutect2, varscan2
- RELB | c.1248C>T p.P416= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs368632431; called by muse, mutect2
- SCN3A | c.3426C>T p.S1142= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as rs1221285213, COSV99327472; called by muse, mutect2
- SMARCAD1 | c.2949T>A p.I983= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as COSV62773889; called by muse, mutect2
- TECTA | c.5520C>T p.I1840= | Silent (SNP) | VAF 12/203 reads (6%) | catalogued as rs762155210, COSV99880365; called by muse, mutect2
- TENM1 | c.7647G>T p.R2549= | Silent (SNP) | VAF 32/528 reads (6%) | catalogued as COSV64424773; called by muse, mutect2
- TPTE | c.36A>C p.G12= | Silent (SNP) | VAF 10/175 reads (6%) | called by muse, mutect2
- UNC13C | c.4065G>A p.K1355= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV52863475; called by muse, mutect2, varscan2
- ZCWPW2 | c.429C>A p.G143= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV101074982, COSV67498766; called by muse, mutect2
- ZKSCAN7 | c.747A>G p.T249= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV99837657; called by muse, mutect2
- CACNA1G | c.4422+207C>T | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs758062279, COSV100662080; called by muse, mutect2, varscan2
- HTR3A | c.917-16G>T | Intron (SNP) | VAF 80/201 reads (40%) | catalogued as COSV55468884; called by muse, mutect2, varscan2
- IGHV1-12 | n.71T>A | RNA (SNP) | VAF 17/225 reads (8%) | called by muse, mutect2
- SNORD116-22 | n.92C>A | RNA (SNP) | VAF 47/398 reads (12%) | called by muse, mutect2, varscan2
- SSX6P | n.94C>A | RNA (SNP) | VAF 30/198 reads (15%) | called by muse, mutect2, varscan2
- THRB | c.284-12783G>A | Intron (SNP) | VAF 43/247 reads (17%) | catalogued as rs547376124, COSV54981120; called by muse, mutect2, varscan2
